Somatic mutation profile of tumor specimen TCGA-CV-7183-01A (aliquot TCGA-CV-7183-01A-11D-2012-08) from TCGA case TCGA-CV-7183, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 53.0 years (19,358 days).
Specimen TCGA-CV-7183-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) acad7dfd-609e-415c-b9ff-132917c46e24.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7183-10A (Blood Derived Normal), aliquot TCGA-CV-7183-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d562d5bb-0e21-4193-b827-a0017b29d4c8

The open-access MAF lists 64 somatic variants for this specimen: 49 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 34, Silent 15, Frame Shift Del 6, Nonsense Mutation 5, Frame Shift Ins 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 7/57 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.385); catalogued as rs104894229, CM053283, CM061797, COSV54236795, COSV54236828, COSV54237299; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.16501C>T p.R5501* | Nonsense Mutation (SNP) | VAF 48/182 reads (26%) | catalogued as rs886041398, CM105482, COSV56407191; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM11 | c.2112G>A p.W704* | Nonsense Mutation (SNP) | VAF 41/182 reads (23%) | catalogued as COSV99567163; called by muse, mutect2, varscan2
- ALG10 | c.1027G>C p.A343P | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as COSV99847949; called by muse, mutect2, varscan2
- ARHGAP39 | c.2035G>A p.V679I | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.019); catalogued as rs141083413; called by muse, mutect2, varscan2
- BICRAL | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | catalogued as COSV100017863; called by muse, mutect2, varscan2
- CA4 | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99958231; called by muse, mutect2, varscan2
- CAT | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as rs139875365; called by muse, mutect2, varscan2
- CD48 | c.646A>G p.T216A | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.22); catalogued as rs1401520766, COSV100924196; called by muse, mutect2, varscan2
- CDKL2 | c.222del p.K74Nfs*5 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs753353408; called by mutect2, varscan2
- CHD8 | c.5362G>T p.E1788* (on ENST00000646647 / NM_001170629.2; = p.E1509* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 28/97 reads (29%) | catalogued as rs1555313584, COSV100765254; called by muse, mutect2, varscan2
- CRNN | c.244G>T p.A82S | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99663950; called by muse, mutect2, varscan2
- EXTL1 | c.1577C>T p.T526M | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.227); catalogued as rs372060207; called by muse, mutect2, varscan2
- FAM135B | c.2109G>T p.R703S | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV52741107, COSV99419731; called by muse, mutect2, varscan2
- FAM78A | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as rs185462653; called by muse, mutect2, varscan2
- FAT1 | c.1874C>A p.S625* | Nonsense Mutation (SNP) | VAF 20/66 reads (30%) | catalogued as COSV101499111; called by muse, mutect2, varscan2
- FAT4 | c.11564G>T p.G3855V | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100627383; called by muse, mutect2, varscan2
- FH | c.138C>G p.S46R | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.052); catalogued as rs1211942353, COSV100844982; called by muse, mutect2, varscan2
- H3C8 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.164); catalogued as COSV100010004, COSV100010026; called by muse, mutect2, varscan2
- HECW2 | c.1648G>A p.G550S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV99646075; called by muse, mutect2, varscan2
- HNRNPD | c.348_349insG p.F117Vfs*6 | Frame Shift Ins (INS) | VAF 25/82 reads (30%) | catalogued as COSV100002755; called by mutect2, pindel, varscan2
- IRF2BP1 | c.597_598del p.K200Afs*119 | Frame Shift Del (DEL) | VAF 49/208 reads (24%) | catalogued as rs1334035190; called by pindel, varscan2
- KCNK5 | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.078); catalogued as COSV100851746, COSV63989432; called by muse, mutect2, varscan2
- LRRC15 | c.1417G>T p.V473F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.023); catalogued as COSV100752568; called by muse, mutect2, varscan2
- MACF1 | c.18785A>T p.K6262M (on ENST00000372915; = p.K4307M on NM_012090.5) | Missense Mutation (SNP) | VAF 27/67 reads (40%) | catalogued as COSV99241738; called by muse, mutect2, varscan2
- MAST1 | c.520G>C p.E174Q | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV52242368, COSV99262410; called by muse, mutect2, varscan2
- OR2T34 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as rs1348194250, COSV100170265; called by mutect2, varscan2
- PAPPA2 | c.4444G>A p.G1482R | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100867627; called by muse, mutect2
- PCDH10 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52105566; called by muse, mutect2, varscan2
- PCDHA13 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.895); catalogued as rs782029001, COSV99165119; called by muse, mutect2, varscan2
- PHACTR3 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.085); catalogued as rs143288140, COSV63027760; called by muse, mutect2, varscan2
- PKHD1L1 | c.10072T>A p.L3358M | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV101005514; called by muse, mutect2, varscan2
- PLXNA1 | c.2618C>T p.T873M | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.206); catalogued as rs549841697, COSV99302406; called by muse, mutect2, varscan2
- PRLHR | c.824G>T p.R275L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs944033499, COSV99492672, COSV99492778; called by muse, mutect2, varscan2
- PSMC6 | c.276A>T p.R92S (on ENST00000612399; = p.R78S on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.767); catalogued as COSV101471183; called by muse, mutect2, varscan2
- SCAF4 | c.1510A>T p.S504C | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99741008; called by muse, mutect2, varscan2
- SCOC | c.226C>A p.P76T (on ENST00000608372; = p.P39T on NM_032547.3) | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV100639561; called by muse, mutect2, varscan2
- STKLD1 | c.342C>A p.S114R | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV100911907; called by muse, mutect2, varscan2
- SYMPK | c.3694G>A p.A1232T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs533280327, COSV99679604; called by muse, varscan2
- TENM2 | c.1900G>T p.D634Y (on ENST00000518659 / NM_001122679.2; = p.D402Y on NM_001080428.3) | Missense Mutation (SNP) | VAF 50/244 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69134685; called by muse, mutect2, varscan2
- UBAP1 | c.743T>C p.L248P | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as COSV99902898; called by muse, mutect2, varscan2
- YOD1 | c.740A>G p.D247G | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as COSV100262891; called by muse, mutect2, varscan2
- ZNF827 | c.1983G>A p.A661= | Splice Region (SNP) | VAF 23/110 reads (21%) | catalogued as rs925471141, COSV101061197; called by muse, mutect2, varscan2
- KSR1 | c.2156_2157del p.Y719* (on ENST00000644974 / NM_001367810.1; = p.Y604* on NM_014238.2) | Frame Shift Del (DEL) | VAF 33/149 reads (22%) | called by mutect2, pindel, varscan2
- NINL | c.1883del p.H628Lfs*13 | Frame Shift Del (DEL) | VAF 15/60 reads (25%) | called by mutect2, pindel, varscan2
- NR2E1 | c.1096del p.T366Pfs*46 | Frame Shift Del (DEL) | VAF 41/175 reads (23%) | called by mutect2, pindel, varscan2
- NUFIP2 | c.1925_1926del p.R642Ifs*9 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by pindel, varscan2
- SRCAP | c.8489dup p.H2830Qfs*3 | Frame Shift Ins (INS) | VAF 15/102 reads (15%) | called by mutect2, pindel, varscan2
- WDTC1 | c.379_380dup p.H128Sfs*11 | Frame Shift Ins (INS) | VAF 9/30 reads (30%) | called by mutect2, pindel, varscan2
- AJAP1 | c.894C>T p.I298= | Silent (SNP) | VAF 43/203 reads (21%) | catalogued as COSV100981513; called by muse, mutect2, varscan2
- ALPK1 | c.690G>T p.P230= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV51583806, COSV99453204; called by muse, mutect2, varscan2
- CHRM2 | c.189C>T p.F63= | Silent (SNP) | VAF 35/133 reads (26%) | catalogued as COSV100280818, COSV100282088; called by muse, mutect2, varscan2
- DRD1 | c.753C>T p.V251= | Silent (SNP) | VAF 29/116 reads (25%) | catalogued as rs147169569, COSV67104192; called by muse, mutect2, varscan2
- DST | c.4872C>T p.L1624= | Silent (SNP) | VAF 56/214 reads (26%) | catalogued as COSV99751822; called by muse, mutect2, varscan2
- FBN3 | c.4449C>A p.G1483= | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as COSV99560039; called by muse, mutect2, varscan2
- FHOD1 | c.2748G>A p.L916= | Silent (SNP) | VAF 42/198 reads (21%) | catalogued as COSV99263885; called by muse, mutect2, varscan2
- GTF3C1 | c.2892G>A p.S964= | Silent (SNP) | VAF 34/112 reads (30%) | catalogued as rs771862807, COSV100649016; called by muse, mutect2, varscan2
- KCNE4 | c.621C>T p.N207= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs1360435701, COSV56054448; called by muse, mutect2, varscan2
- KLHL1 | c.528T>G p.P176= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV100917057; called by muse, mutect2, varscan2
- MAPKBP1 | c.1749C>T p.R583= (on ENST00000456763 / NM_001128608.2; = p.R577= on NM_014994.3) | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV99528996; called by muse, mutect2, varscan2
- PDS5A | c.93G>A p.E31= | Silent (SNP) | VAF 38/152 reads (25%) | catalogued as COSV100337198; called by muse, mutect2, varscan2
- PIGR | c.1206G>A p.E402= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100732446; called by muse, mutect2, varscan2
- RNF113B | c.666C>T p.L222= | Silent (SNP) | VAF 35/134 reads (26%) | catalogued as rs761529542, COSV57435368; called by muse, mutect2, varscan2
- TP53BP1 | c.723G>A p.Q241= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as COSV99779624, COSV99779904; called by muse, mutect2, varscan2
